Somatic mutation profile of tumor specimen ALCH-B1KA-TTP1-A (aliquot ALCH-B1KA-TTP1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-B1KA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 77.4 years (28,288 days).
Specimen ALCH-B1KA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 643472cf-c833-487b-b226-f93b14e55f15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1KA-NB1-A (Blood Derived Normal), aliquot ALCH-B1KA-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b27d96d5-3a0c-4753-bed7-7b1edc19d0e0

The open-access MAF lists 532 somatic variants for this specimen: 391 protein-altering or splice-affecting, 82 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 356, Silent 82, Intron 22, Nonsense Mutation 16, RNA 12, 3'UTR 10, 5'UTR 8, Splice Site 7, Frame Shift Del 5, 5'Flank 4, 3'Flank 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 207/703 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSS1 | c.1219C>A p.R407S | Missense Mutation (SNP) | VAF 87/272 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60217987; called by muse, mutect2, varscan2
- ADAM28 | c.1711G>T p.D571Y | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs767072648; called by muse, mutect2, varscan2
- ADGB | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 18/200 reads (9%) | catalogued as rs1054105863; called by muse, mutect2
- AKAP6 | c.5392A>G p.I1798V | Missense Mutation (SNP) | VAF 88/466 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs764059329, COSV55235701; called by muse, mutect2, varscan2
- APOB | c.2335A>G p.I779V | Missense Mutation (SNP) | VAF 66/328 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs763559077; called by muse, mutect2, varscan2
- BEND4 | c.1579A>G p.S527G | Missense Mutation (SNP) | VAF 61/337 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101549765; called by muse, mutect2, varscan2
- BTBD8 | c.5344G>A p.E1782K (on ENST00000636805 / NM_001376131.1; = p.E1269K on NM_015237.4) | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1162835777; called by muse, mutect2
- BUB1B | c.1774A>G p.I592V | Missense Mutation (SNP) | VAF 83/431 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as rs1225598259; called by muse, mutect2, varscan2
- C3 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 42/477 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1348311492, COSV55581886; ClinVar: uncertain significance; called by muse, mutect2
- C9 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 41/915 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as COSV54676472; called by muse, mutect2
- CCDC60 | c.1041-2A>C p.X347_splice | Splice Site (SNP) | VAF 75/464 reads (16%) | catalogued as COSV100555811; called by muse, mutect2, varscan2
- CDH18 | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 297/615 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV56934961; called by muse, mutect2, varscan2
- CEP250 | c.4496G>A p.R1499Q | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs756362141, COSV61168263; called by muse, mutect2
- CLDN22 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 50/313 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs750503626; called by muse, mutect2, varscan2
- CNR1 | c.675G>C p.K225N | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62986555; called by muse, mutect2, varscan2
- CNTNAP5 | c.2633G>T p.R878L | Missense Mutation (SNP) | VAF 130/679 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs781364259; called by muse, mutect2, varscan2
- COL6A6 | c.2104G>A p.G702S | Missense Mutation (SNP) | VAF 83/420 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100650403; called by muse, mutect2, varscan2
- CPQ | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 45/543 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV55161223; called by muse, mutect2
- CSMD1 | c.6737T>C p.F2246S (on ENST00000520002; = p.F2245S on NM_033225.6) | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV59289016; called by muse, mutect2
- CTSE | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.034); catalogued as rs781951953; called by muse, mutect2
- CUL1 | c.1914A>C p.Q638H | Missense Mutation (SNP) | VAF 41/471 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57389547; called by muse, mutect2
- CUX1 | c.2062G>T p.A688S | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); catalogued as COSV99472578; called by muse, mutect2, varscan2
- DAB2 | c.788G>A p.C263Y | Missense Mutation (SNP) | VAF 42/1118 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as COSV57920103; called by muse, mutect2
- DENND2A | c.2800C>A p.R934S | Missense Mutation (SNP) | VAF 147/553 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV52050299, COSV99326827; called by muse, mutect2, varscan2
- DNAAF5 | c.1259G>A p.C420Y | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1466619354; called by muse, mutect2
- DNAH3 | c.6839G>T p.R2280L | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780583687, COSV54506885; called by muse, mutect2, varscan2
- DNMT3A | c.1687G>C p.V563L | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53045040; called by mutect2, varscan2
- DOCK10 | c.4778A>C p.K1593T | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99292752; called by muse, mutect2
- EBF4 | c.1781G>T p.R594L (on ENST00000609451; = p.R590L on NM_001110514.1) | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV61356256; called by muse, mutect2
- ELOVL4 | c.444A>C p.R148S | Missense Mutation (SNP) | VAF 59/422 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63953452; called by muse, mutect2, varscan2
- FAM107B | c.74A>C p.K25T (on ENST00000378458 / NM_001320737.1; = p.K200T on NM_031453.3) | Missense Mutation (SNP) | VAF 56/542 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51690214; called by muse, mutect2, varscan2
- FAT2 | c.6206A>C p.K2069T | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1366230230; called by muse, mutect2, varscan2
- FBXL8 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs936141543; called by muse, mutect2, varscan2
- FCN1 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs149439264; called by muse, mutect2, varscan2
- FERMT3 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs752432697; called by muse, mutect2, varscan2
- FLG | c.3307G>A p.A1103T | Missense Mutation (SNP) | VAF 116/610 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs546349534, COSV100910409; called by muse, mutect2, varscan2
- FREM1 | c.1304A>G p.E435G | Missense Mutation (SNP) | VAF 43/450 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs1371541475; called by muse, mutect2, varscan2
- FREM2 | c.8675A>T p.D2892V | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs757325874; called by muse, mutect2, varscan2
- GAB1 | c.1738A>G p.S580G | Missense Mutation (SNP) | VAF 46/347 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs748613957; called by muse, varscan2
- GIMAP8 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56230603; called by muse, mutect2
- GOLGA8Q | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 28/533 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as rs1397614418; called by muse, mutect2
- GPR63 | c.139A>G p.S47G | Missense Mutation (SNP) | VAF 120/503 reads (24%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs959059003; called by muse, mutect2, varscan2
- HAPLN4 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52269580; called by muse, mutect2, varscan2
- HEPACAM | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.497); catalogued as rs149093986; ClinVar: likely benign; called by muse, mutect2, varscan2
- HOXA6 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.108); catalogued as rs779257098; called by muse, varscan2
- IAPP | c.-15-1G>T | Splice Site (SNP) | VAF 48/292 reads (16%) | catalogued as COSV53714478; called by muse, mutect2, varscan2
- IGHV1-18 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 54/572 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs550527608; called by muse, mutect2
- IGHV3-20 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 80/319 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.051); catalogued as rs113043950; called by muse, mutect2, varscan2
- IKBKE | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 155/578 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs782430885, COSV65624232; called by muse, mutect2, varscan2
- IL7R | c.638T>G p.F213C | Missense Mutation (SNP) | VAF 51/1476 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57411431; called by muse, mutect2
- KCNH1 | c.529A>T p.N177Y | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV55092858; called by muse, mutect2, varscan2
- KIAA0825 | c.3259C>T p.R1087C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1175421668; called by muse, mutect2, varscan2
- KIR2DL1 | c.818-2A>T p.X273_splice | Splice Site (SNP) | VAF 25/162 reads (15%) | catalogued as rs1390028106, COSV52412000; called by muse, mutect2, varscan2
- LIPG | c.963C>A p.Y321* | Nonsense Mutation (SNP) | VAF 129/824 reads (16%) | catalogued as rs767013952; called by muse, mutect2, varscan2
- LTBP1 | c.4205C>G p.P1402R (on ENST00000404816 / NM_206943.4; = p.P1076R on NM_000627.4) | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55379315; called by muse, varscan2
- MAP2K4 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs1415316526; called by muse, mutect2
- METTL2B | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 74/347 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs760621027; called by muse, mutect2, varscan2
- MGA | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99578314; called by muse, mutect2, varscan2
- MMP10 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 15/363 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV99666307; called by muse, mutect2
- MRFAP1 | c.38A>C p.E13A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1160534700, COSV57994626; called by muse, mutect2
- MUC16 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 84/312 reads (27%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs370920501; called by muse, mutect2, varscan2
- NALCN | c.3700G>T p.E1234* | Nonsense Mutation (SNP) | VAF 70/343 reads (20%) | catalogued as COSV51930185, COSV51963378; called by muse, mutect2, varscan2
- NAV2 | c.3097C>T p.R1033W (on ENST00000396087 / NM_001244963.2; = p.R1010W on NM_145117.5) | Missense Mutation (SNP) | VAF 51/472 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs199543112; called by muse, mutect2, varscan2
- NEUROD4 | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 51/365 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99670002; called by muse, mutect2, varscan2
- NIPBL | c.4766G>A p.G1589E | Missense Mutation (SNP) | VAF 66/1318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CX107676, COSV99242883; called by muse, mutect2
- NME8 | c.1537T>G p.L513V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV52251585; called by muse, mutect2
- NODAL | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1166158482; called by muse, mutect2, varscan2
- OPLAH | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 33/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101470852; called by muse, mutect2
- OR2A25 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 48/719 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1439504242, COSV101376375; called by muse, mutect2
- OR4D5 | c.515A>G p.D172G | Missense Mutation (SNP) | VAF 50/492 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV58309526; called by muse, mutect2, varscan2
- OR4K1 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 85/418 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs746934178; called by muse, mutect2, varscan2
- OR4L1 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1476953868, COSV59849836; called by muse, mutect2
- OR4M1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 102/603 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs972220382; called by muse, mutect2, varscan2
- OR8I2 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 85/363 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV56169726, COSV56170425; called by muse, mutect2, varscan2
- PABPC3 | c.89A>C p.K30T | Missense Mutation (SNP) | VAF 22/285 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV99878822; called by muse, mutect2
- PDCD4 | c.876A>T p.R292S | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1435285762; called by muse, mutect2, varscan2
- PLCB4 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV53797007; called by muse, mutect2
- PLCD1 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs531907199, COSV99378790; called by muse, mutect2, varscan2
- PLEKHH1 | c.904A>G p.R302G | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV100233393; called by muse, mutect2, varscan2
- POGLUT2 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 46/211 reads (22%) | catalogued as COSV57278237; called by muse, mutect2, varscan2
- PPP4R2 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV55596228; called by muse, mutect2, varscan2
- PRLR | c.940T>C p.Y314H | Missense Mutation (SNP) | VAF 52/968 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV51493346; called by muse, mutect2
- PTK2B | c.2709del p.E904Rfs*7 | Frame Shift Del (DEL) | VAF 30/148 reads (20%) | catalogued as rs869044240; called by mutect2, varscan2
- PXDNL | c.1843C>T p.L615F | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as COSV62494809; called by muse, mutect2
- RET | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 63/585 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1356141763, COSV60707014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGSL1 | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1326048160; called by muse, mutect2
- RIMS2 | c.759A>T p.R253S (on ENST00000666250 / NM_001348490.2; = p.R61S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as COSV51686042; called by muse, mutect2, varscan2
- RNF175 | c.378del p.K126Nfs*17 | Frame Shift Del (DEL) | VAF 23/183 reads (13%) | catalogued as COSV56841299; called by mutect2, pindel, varscan2
- SCN7A | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101313038; called by muse, mutect2, varscan2
- SCP2D1 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 47/408 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.197); catalogued as COSV53859133; called by muse, mutect2, varscan2
- SHROOM3 | c.4342G>A p.A1448T | Missense Mutation (SNP) | VAF 74/510 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs781548863; called by muse, mutect2, varscan2
- SMO | c.1691A>C p.K564T | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50835208; called by muse, mutect2, varscan2
- SPATA31E1 | c.3461A>G p.Q1154R | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); catalogued as rs371526132; called by muse, mutect2, varscan2
- SPTA1 | c.294A>T p.E98D | Missense Mutation (SNP) | VAF 202/703 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV63749427; called by muse, mutect2, varscan2
- STXBP5 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1337120783; called by muse, mutect2
- SYCP1 | c.928T>G p.L310V | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV65701430; called by muse, mutect2, varscan2
- TCERG1L | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64057286; called by muse, mutect2, varscan2
- TDRD15 | c.4654A>C p.I1552L | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV68267593; called by muse, mutect2, varscan2
- TEK | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 91/792 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs1464003209; called by muse, mutect2, varscan2
- TET2 | c.2635C>T p.L879F | Missense Mutation (SNP) | VAF 71/603 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV99483827; called by muse, mutect2, varscan2
- TOX | c.776A>G p.N259S | Missense Mutation (SNP) | VAF 137/655 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1311831116; called by muse, mutect2, varscan2
- TRO | c.2437T>G p.F813V | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV51506054; called by muse, mutect2, varscan2
- TRPM3 | c.590T>G p.L197R (on ENST00000357533 / NM_001366142.2; = p.L42R on NM_020952.6) | Missense Mutation (SNP) | VAF 66/770 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV62468425; called by muse, mutect2
- UGT2B4 | c.749T>C p.M250T | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs757167691; called by muse, mutect2, varscan2
- UNC5B | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs781171880, COSV58978017; called by muse, varscan2
- VSTM2A | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 175/561 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs775572838; called by muse, mutect2, varscan2
- ZDBF2 | c.1361G>T p.C454F | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.306); catalogued as rs530413642; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 62/570 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as rs766430041; called by muse, mutect2, varscan2
- ZNF404 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV60987217; called by muse, mutect2
- ZNF582 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs746507547, COSV56732489; called by muse, mutect2, varscan2
- ZNF628 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs867628256; called by muse, mutect2, varscan2
- ZRANB3 | c.635G>C p.R212T | Missense Mutation (SNP) | VAF 59/434 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51494224, COSV51495887; called by muse, mutect2, varscan2
- ZSWIM2 | c.1402G>C p.D468H | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV54580418; called by muse, mutect2, varscan2
- ABCA8 | c.420G>T p.L140F | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCA9 | c.2783A>C p.N928T | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- ACTRT1 | c.1122G>T p.R374S | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2
- ADAM7 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4080A>C p.E1360D | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADCY2 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 50/364 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 177/624 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGB | c.4400C>T p.S1467L | Missense Mutation (SNP) | VAF 87/864 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AFDN | c.3716A>G p.Q1239R | Missense Mutation (SNP) | VAF 70/402 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- AFF2 | c.1895A>C p.K632T | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2
- AHNAK | c.11432A>C p.K3811T | Missense Mutation (SNP) | VAF 70/630 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AKAP9 | c.8303A>T p.K2768I (on ENST00000359028; = p.K2744I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- AL592490.1 | c.2606A>G p.E869G | Missense Mutation (SNP) | VAF 53/467 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALDH8A1 | c.1397del p.G466Vfs*26 | Frame Shift Del (DEL) | VAF 84/392 reads (21%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.3266A>C p.Q1089P (on ENST00000611781; = p.Q1033P on NM_052997.2) | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ANKS4B | c.90A>C p.E30D | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2
- AOAH | c.500A>C p.K167T | Missense Mutation (SNP) | VAF 35/486 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.107); called by muse, mutect2
- APP | c.992T>G p.F331C | Missense Mutation (SNP) | VAF 89/723 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ASZ1 | c.991A>C p.K331Q | Missense Mutation (SNP) | VAF 84/343 reads (24%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- AWAT2 | c.962A>C p.K321T | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- BACE2 | c.1011G>C p.W337C | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BARHL1 | c.827C>A p.A276E | Missense Mutation (SNP) | VAF 81/255 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- BMS1 | c.3752A>C p.Q1251P | Missense Mutation (SNP) | VAF 47/516 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- BOD1L1 | c.7216G>A p.E2406K | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- BPI | c.1340G>T p.R447M (on ENST00000262865; = p.R443M on NM_001725.3) | Missense Mutation (SNP) | VAF 118/409 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- BRCC3 | c.530A>T p.Q177L | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- BRWD1 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- BSCL2 | c.218A>T p.D73V | Missense Mutation (SNP) | VAF 145/622 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C5AR1 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 53/412 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CAMK1G | c.908A>C p.K303T | Missense Mutation (SNP) | VAF 78/342 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CCDC39 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CCDC69 | c.674A>C p.D225A | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CDADC1 | c.207A>T p.L69F | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- CDH2 | c.470A>G p.Q157R | Missense Mutation (SNP) | VAF 54/614 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.151); called by muse, mutect2
- CEP350 | c.7166C>A p.S2389* | Nonsense Mutation (SNP) | VAF 60/258 reads (23%) | called by muse, mutect2, varscan2
- CFH | c.2812T>C p.S938P | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2
- CFHR1 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 48/244 reads (20%) | called by muse, varscan2
- CLCNKA | c.1186T>C p.F396L | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CNNM1 | c.2720G>A p.S907N | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CNOT8 | c.-1_10del | Translation Start Site (DEL) | VAF 24/232 reads (10%) | called by mutect2, pindel
- CNTLN | c.1519-2A>G p.X507_splice | Splice Site (SNP) | VAF 26/297 reads (9%) | called by muse, mutect2
- CNTN4 | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 44/404 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- COL5A3 | c.3812G>C p.G1271A | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL6A5 | c.293_310del p.K98_F103del | In Frame Del (DEL) | VAF 21/134 reads (16%) | called by mutect2, pindel
- COL8A1 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); called by muse, mutect2
- COL8A1 | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.287); called by muse, mutect2
- COLEC11 | c.474G>C p.K158N | Missense Mutation (SNP) | VAF 79/342 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- COMMD6 | c.45C>A p.V15= | Splice Region (SNP) | VAF 23/214 reads (11%) | called by muse, mutect2, varscan2
- CSMD2 | c.1712A>C p.K571T | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); called by muse, mutect2
- CTH | c.587A>T p.Q196L | Missense Mutation (SNP) | VAF 66/397 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYP2C8 | c.362A>T p.K121M | Missense Mutation (SNP) | VAF 58/462 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DAAM2 | c.2063T>G p.L688W | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DARS1 | c.1381T>A p.F461I | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2
- DCDC1 | c.4781C>A p.P1594Q (on ENST00000597505 / NM_001367979.1; = p.P701Q on NM_020869.3) | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2
- DCTN2 | c.1069C>T p.Q357* (on ENST00000548249 / NM_001261413.2; = p.Q362* on NM_006400.4) | Nonsense Mutation (SNP) | VAF 38/559 reads (7%) | called by muse, mutect2
- DLC1 | c.1880C>A p.S627Y (on ENST00000276297 / NM_001348081.2; = p.S190Y on NM_006094.5) | Missense Mutation (SNP) | VAF 76/320 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DNAI1 | c.1780T>C p.S594P | Missense Mutation (SNP) | VAF 64/798 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.288); called by muse, mutect2
- DNAJC16 | c.18G>T p.L6F | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.561); called by muse, varscan2
- DSCAM | c.4899T>G p.S1633R | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- DSCAM | c.2356+2T>C p.X786_splice | Splice Site (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- DSEL | c.2918G>A p.R973K | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EBF4 | c.1216T>C p.Y406H (on ENST00000609451; = p.Y402H on NM_001110514.1) | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- EGF | c.1438+2T>A p.X480_splice | Splice Site (SNP) | VAF 64/530 reads (12%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERICH3 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 95/357 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ETV1 | c.1280C>A p.P427Q | Missense Mutation (SNP) | VAF 136/588 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EVC | c.1843A>G p.T615A | Missense Mutation (SNP) | VAF 54/682 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- FAM135B | c.2644A>C p.I882L | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM166C | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- FAM181B | c.1179C>A p.Y393* | Nonsense Mutation (SNP) | VAF 25/161 reads (16%) | called by muse, mutect2, varscan2
- FAM227B | c.602T>G p.L201R | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, varscan2
- FAT2 | c.8702A>C p.D2901A | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT4 | c.10651C>A p.L3551M | Missense Mutation (SNP) | VAF 53/371 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAXDC2 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FBXL7 | c.983A>C p.E328A | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2
- FBXO10 | c.1843A>T p.R615W | Missense Mutation (SNP) | VAF 50/631 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FETUB | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FGD6 | c.1792C>A p.L598I | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FKBP6 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 129/520 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- FLG2 | c.6005C>T p.A2002V | Missense Mutation (SNP) | VAF 60/599 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FLT3 | c.1309A>C p.R437= | Splice Region (SNP) | VAF 34/274 reads (12%) | called by muse, varscan2
- FMN2 | c.3470T>G p.L1157R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); called by muse, varscan2
- FMO3 | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 116/505 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FRMPD2 | c.2712T>A p.N904K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by mutect2, varscan2
- FRS2 | c.754G>C p.V252L | Missense Mutation (SNP) | VAF 58/406 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FRYL | c.5686C>A p.Q1896K | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- GABRB1 | c.510G>C p.L170F | Missense Mutation (SNP) | VAF 102/640 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- GAD2 | c.1412T>C p.V471A | Missense Mutation (SNP) | VAF 48/476 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- GBP6 | c.125C>G p.A42G | Missense Mutation (SNP) | VAF 88/371 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- GDAP1 | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 73/781 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2
- GGA1 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- GJA10 | c.1398C>A p.S466R | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- GLP2R | c.482A>T p.E161V | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- GLRB | c.527+2T>C p.X176_splice | Splice Site (SNP) | VAF 67/262 reads (26%) | called by muse, mutect2, varscan2
- GPR55 | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 34/404 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.475); called by muse, mutect2
- GREM2 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 23/302 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.173); called by muse, mutect2
- GRK3 | c.612A>C p.E204D | Missense Mutation (SNP) | VAF 48/508 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- GRK3 | c.904A>G p.I302V | Missense Mutation (SNP) | VAF 79/426 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- GRM5 | c.3158C>A p.S1053* (on ENST00000305447 / NM_001143831.2; = p.S1021* on NM_000842.4) | Nonsense Mutation (SNP) | VAF 24/268 reads (9%) | called by muse, mutect2
- GRM8 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.115); called by muse, mutect2
- GUCY1A1 | c.1168T>G p.L390V | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HACE1 | c.2504T>G p.V835G | Missense Mutation (SNP) | VAF 40/440 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- HCN1 | c.1751A>G p.E584G | Missense Mutation (SNP) | VAF 70/1813 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- HDDC2 | c.312A>C p.E104D | Missense Mutation (SNP) | VAF 59/447 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HEXIM1 | c.622T>C p.F208L | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HNF4A | c.1094A>C p.K365T | Missense Mutation (SNP) | VAF 50/526 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- IGHV3OR16-8 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.342); called by muse, mutect2
- IGKV1D-12 | c.297C>G p.S99R | Missense Mutation (SNP) | VAF 81/549 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- IGKV3-11 | c.245T>C p.F82S | Missense Mutation (SNP) | VAF 40/702 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- IL16 | c.2009A>C p.K670T | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- IL1R2 | c.553A>C p.S185R | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IL7R | c.880T>G p.L294V | Missense Mutation (SNP) | VAF 55/1497 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2
- ING1 | c.166G>T p.V56F | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.756); called by muse, mutect2
- ITIH5 | c.1654G>T p.A552S | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KCND3 | c.537C>A p.S179R | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- KCNH1 | c.2933C>A p.S978Y (on ENST00000271751 / NM_172362.3; = p.S951Y on NM_002238.4) | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); called by muse, mutect2
- KCNQ3 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KDM2B | c.1001A>G p.N334S | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- KIAA2026 | c.4679A>G p.K1560R | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- KIF4B | c.3112A>G p.S1038G | Missense Mutation (SNP) | VAF 98/753 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KIF6 | c.1034T>A p.I345K | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL40 | c.1820C>A p.T607N | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- KPRP | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 83/638 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KRTAP13-4 | c.335T>A p.F112Y | Missense Mutation (SNP) | VAF 84/308 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KRTAP6-1 | c.80A>T p.Y27F | Missense Mutation (SNP) | VAF 87/436 reads (20%) | PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- L3MBTL1 | c.1241G>T p.R414I (on ENST00000418998 / NM_001377303.1; = p.R324I on NM_015478.7) | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- LAMA3 | c.933C>A p.N311K | Missense Mutation (SNP) | VAF 43/736 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- LIMCH1 | c.1922A>C p.K641T | Missense Mutation (SNP) | VAF 30/655 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2
- LIN28A | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 94/306 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- LRP1B | c.10705A>C p.K3569Q | Missense Mutation (SNP) | VAF 46/549 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.108); called by muse, mutect2
- LSM1 | c.28del p.L10Sfs*20 | Frame Shift Del (DEL) | VAF 49/267 reads (18%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.1159T>C p.Y387H | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MAPT | c.946C>A p.Q316K (on ENST00000262410 / NM_001377265.1; = p.Q241K on NM_016835.4) | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.037); called by mutect2, varscan2
- MAT2A | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 50/664 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MGAM2 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 62/334 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MORC1 | c.101A>C p.E34A | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MORC2 | c.1757C>T p.S586F (on ENST00000397641 / NM_001303256.3; = p.S524F on NM_014941.3) | Missense Mutation (SNP) | VAF 117/449 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MS4A3 | c.249T>G p.F83L | Missense Mutation (SNP) | VAF 51/421 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- MXRA5 | c.3492C>A p.H1164Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYCN | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- MYO18A | c.1142A>C p.K381T | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.365); called by muse, mutect2
- NAB2 | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NBEA | c.1756C>G p.H586D | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.14); called by muse, mutect2
- NBEA | c.7274A>G p.Q2425R | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.435); called by muse, mutect2
- NID2 | c.2208A>C p.E736D | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- NLRP3 | c.1283A>G p.K428R | Missense Mutation (SNP) | VAF 49/372 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NOTCH3 | c.4304G>C p.R1435P | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- NTNG1 | c.441C>G p.N147K | Missense Mutation (SNP) | VAF 96/548 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- OCLN | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- OLA1 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 68/385 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- OPCML | c.228C>G p.Y76* | Nonsense Mutation (SNP) | VAF 32/320 reads (10%) | called by muse, mutect2
- OR10G9 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR10S1 | c.272T>A p.V91E | Missense Mutation (SNP) | VAF 54/546 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2
- OR11H1 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.114); called by mutect2, varscan2
- OR12D3 | c.526T>C p.F176L | Missense Mutation (SNP) | VAF 57/471 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- OR2AK2 | c.685A>C p.S229R | Missense Mutation (SNP) | VAF 27/308 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.022); called by muse, mutect2
- OR4Q2 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 133/610 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- OR4S1 | c.878A>C p.K293T | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR51L1 | c.365T>G p.F122C | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR56A5 | c.668T>G p.F223C | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR5M11 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR5W2 | c.560T>A p.L187H | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR8G5 | c.676C>A p.L226I | Missense Mutation (SNP) | VAF 42/408 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.66); called by muse, varscan2
- ORC2 | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- OSBPL1A | c.785T>G p.V262G | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- OTOG | c.2369T>C p.V790A | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OXR1 | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 28/395 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); called by muse, mutect2
- PABPC4 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARVA | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 74/302 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PDYN | c.244T>A p.L82M | Missense Mutation (SNP) | VAF 43/332 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- PEG3 | c.4551C>A p.S1517R | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- PHF1 | c.1303T>G p.F435V | Missense Mutation (SNP) | VAF 30/365 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2
- PKHD1L1 | c.11104C>A p.Q3702K | Missense Mutation (SNP) | VAF 123/576 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PKN2 | c.1337T>G p.V446G | Missense Mutation (SNP) | VAF 42/508 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLCB4 | c.2396T>G p.I799S | Missense Mutation (SNP) | VAF 54/748 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- PLCL1 | c.836A>G p.K279R | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.02); called by muse, mutect2
- POLR3E | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PPARG | c.989G>A p.S330N (on ENST00000287820 / NM_015869.5; = p.S300N on NM_005037.7) | Missense Mutation (SNP) | VAF 27/358 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- PRRC2A | c.2855T>C p.I952T | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PRSS58 | c.136A>C p.I46L | Missense Mutation (SNP) | VAF 34/459 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2
- PTCH2 | c.2627C>A p.A876D | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTGER1 | c.1043C>G p.P348R | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTK2B | c.2705C>A p.P902H | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- PTPRM | c.2789G>C p.G930A | Missense Mutation (SNP) | VAF 47/333 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRQ | c.2587A>T p.K863* (on ENST00000616559; = p.K821* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.5645A>T p.Q1882L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- RAB3GAP1 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 100/471 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RAD23A | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 35/392 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- RBBP8 | c.1845A>T p.Q615H | Missense Mutation (SNP) | VAF 161/931 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RELN | c.2557G>C p.V853L | Missense Mutation (SNP) | VAF 107/472 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- RGSL1 | c.2122C>T p.P708S | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2
- RNF121 | c.507G>T p.K169N | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- RNF217 | c.539A>G p.E180G | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SAGE1 | c.1730C>A p.T577N | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SALL2 | c.2056G>C p.A686P | Missense Mutation (SNP) | VAF 84/389 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- SATB1 | c.866C>A p.S289Y | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- SCGN | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SCN7A | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCUBE2 | c.2765C>T p.T922I (on ENST00000649792 / NM_001367977.2; = p.T865I on NM_020974.3) | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINI1 | c.316A>G p.M106V | Missense Mutation (SNP) | VAF 53/440 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SETDB1 | c.2006A>C p.K669T | Missense Mutation (SNP) | VAF 24/801 reads (3%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.614); called by muse, mutect2
- SHB | c.570C>A p.S190R | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SIGLEC1 | c.2867G>A p.G956E | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIRPD | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 52/489 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SLC11A2 | c.329G>A p.S110N (on ENST00000394904 / NM_001379455.1; = p.S81N on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/540 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC16A7 | c.131T>G p.F44C | Missense Mutation (SNP) | VAF 31/484 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SLC26A11 | c.1501A>G p.I501V | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC38A5 | c.391_394del p.I131Vfs*37 | Frame Shift Del (DEL) | VAF 86/192 reads (45%) | called by mutect2, pindel, varscan2
- SLC39A2 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- SLC4A3 | c.3425C>A p.P1142H | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC8A1 | c.1475T>G p.L492R | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2
- SLC8A3 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 110/498 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLIT1 | c.2077A>T p.T693S | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SMARCE1 | c.357C>A p.Y119* | Nonsense Mutation (SNP) | VAF 92/204 reads (45%) | called by muse, mutect2, varscan2
- SMC1B | c.1773T>A p.C591* | Nonsense Mutation (SNP) | VAF 26/203 reads (13%) | called by muse, mutect2, varscan2
- SNX10 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 67/550 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SORCS3 | c.3424T>G p.L1142V | Missense Mutation (SNP) | VAF 33/316 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SOX14 | c.209A>C p.K70T | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- SP8 | c.251C>T p.S84F (on ENST00000361443 / NM_198956.4; = p.S102F on NM_182700.6) | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2
- SPAG17 | c.3183A>C p.K1061N | Missense Mutation (SNP) | VAF 40/590 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SPATA48 | c.729A>T p.K243N | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPTB | c.3580T>A p.L1194M | Missense Mutation (SNP) | VAF 37/369 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SPTBN1 | c.1490dup p.R498Afs*49 | Frame Shift Ins (INS) | VAF 72/667 reads (11%) | called by mutect2, pindel, varscan2
- SRPRA | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUGCT | c.1082A>T p.E361V | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2
- SYT1 | c.893A>C p.K298T | Missense Mutation (SNP) | VAF 26/369 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- TAAR8 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 17/525 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2
- TBC1D7 | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 36/357 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); called by muse, mutect2
- TBX5 | c.527T>G p.M176R | Missense Mutation (SNP) | VAF 76/598 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCF20 | c.278C>A p.A93E | Missense Mutation (SNP) | VAF 75/414 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TDRD15 | c.2131A>C p.N711H | Missense Mutation (SNP) | VAF 19/254 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.098); called by muse, mutect2
- TEK | c.2184A>C p.E728D | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.352); called by muse, mutect2
- TG | c.1425A>C p.K475N | Missense Mutation (SNP) | VAF 72/773 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); called by muse, mutect2
- THSD4 | c.1066T>C p.F356L | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TLL2 | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TMEM108 | c.423C>G p.I141M | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM59L | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMX4 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- TNKS | c.628A>G p.K210E | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TONSL | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2
- TOX2 | c.809A>G p.Q270R (on ENST00000358131 / NM_001098798.2; = p.Q219R on NM_032883.3) | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TP53BP1 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 37/474 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.156); called by muse, mutect2
- TTLL2 | c.1541G>T p.R514M | Missense Mutation (SNP) | VAF 125/537 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTN | c.24065A>T p.D8022V (on ENST00000591111; = p.D7095V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/168 reads (11%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.11842C>T p.Q3948* (on ENST00000591111; = p.Q3902* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- TUB | c.116A>C p.K39T (on ENST00000299506 / NM_177972.3; = p.K94T on NM_003320.4) | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- TUBA3D | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); called by muse, mutect2
- UBE2L6 | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- UBQLN3 | c.1846T>G p.F616V | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- UBR5 | c.7108A>C p.I2370L | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- UGT3A1 | c.1562A>G p.K521R | Missense Mutation (SNP) | VAF 21/323 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- UNC5D | c.2511A>C p.Q837H | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC79 | c.7352T>G p.L2451R (on ENST00000393151 / NM_001346218.2; = p.L2274R on NM_020818.5) | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- URB1 | c.6352G>T p.A2118S | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2
- USH2A | c.7096A>C p.T2366P | Missense Mutation (SNP) | VAF 52/469 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- USP6NL | c.909C>G p.I303M | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- UTP14C | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 135/607 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- UTRN | c.6380A>T p.Q2127L | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VWA3B | c.2021A>C p.N674T | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, varscan2
- WDR17 | c.1513T>C p.C505R | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR7 | c.3669G>A p.M1223I | Missense Mutation (SNP) | VAF 211/868 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- WDR72 | c.1951T>G p.S651A | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- XRN2 | c.426A>G p.K142= | Splice Region (SNP) | VAF 38/309 reads (12%) | called by muse, mutect2, varscan2
- ZBTB10 | c.2471A>C p.Q824P (on ENST00000430430; = p.Q800P on NM_023929.4) | Missense Mutation (SNP) | VAF 81/611 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ZBTB37 | c.489dup p.S164* | Frame Shift Ins (INS) | VAF 69/274 reads (25%) | called by mutect2, pindel, varscan2
- ZDBF2 | c.2935T>C p.W979R | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFYVE26 | c.4432G>T p.A1478S | Missense Mutation (SNP) | VAF 65/426 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF106 | c.192A>C p.E64D | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ZNF155 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ZNF17 | c.362T>G p.L121R | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF527 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 18/327 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF536 | c.3439A>T p.I1147F | Missense Mutation (SNP) | VAF 128/2780 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); called by muse, mutect2
- ZNF569 | c.1952T>A p.L651H | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF652 | c.1616C>G p.P539R | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.247); called by muse, mutect2
- ZNF782 | c.752A>C p.N251T | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.007); called by muse, mutect2
- ZSCAN20 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZUP1 | c.491A>G p.E164G | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC4 | c.3534T>C p.S1178= | Silent (SNP) | VAF 17/243 reads (7%) | catalogued as rs1168133939; called by muse, mutect2
- ADAMTSL1 | c.2670C>G p.L890= | Silent (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- ADRB3 | c.597C>G p.A199= | Silent (SNP) | VAF 20/444 reads (5%) | called by muse, mutect2
- ARAP3 | c.2862G>A p.L954= | Silent (SNP) | VAF 38/321 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.2289G>A p.E763= | Silent (SNP) | VAF 15/240 reads (6%) | called by muse, mutect2
- ARHGEF26 | c.444G>T p.R148= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as rs772726508; called by muse, mutect2
- C1orf53 | c.237C>T p.I79= | Silent (SNP) | VAF 10/61 reads (16%) | called by muse, varscan2
- C3 | c.3420C>T p.D1140= | Silent (SNP) | VAF 41/804 reads (5%) | called by muse, mutect2
- C5orf49 | c.168T>C p.Y56= | Silent (SNP) | VAF 28/501 reads (6%) | called by muse, mutect2
- C8orf82 | c.429G>C p.A143= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99430350; called by muse, mutect2
- CCN3 | c.144G>T p.P48= | Silent (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- CEMIP | c.579C>T p.V193= | Silent (SNP) | VAF 92/642 reads (14%) | called by muse, mutect2, varscan2
- CFAP65 | c.909C>T p.I303= | Silent (SNP) | VAF 33/352 reads (9%) | called by muse, mutect2
- COL20A1 | c.450T>G p.S150= | Silent (SNP) | VAF 17/198 reads (9%) | called by muse, mutect2
- COL6A3 | c.2958C>T p.I986= | Silent (SNP) | VAF 69/332 reads (21%) | catalogued as rs145203676; called by muse, mutect2, varscan2
- COL9A1 | c.360T>C p.T120= | Silent (SNP) | VAF 58/484 reads (12%) | called by muse, mutect2, varscan2
- CPS1 | c.2082G>T p.V694= | Silent (SNP) | VAF 48/613 reads (8%) | called by muse, mutect2
- CRABP2 | c.201G>A p.K67= | Silent (SNP) | VAF 93/242 reads (38%) | called by muse, mutect2, varscan2
- CRACD | c.2436C>T p.A812= | Silent (SNP) | VAF 93/712 reads (13%) | catalogued as COSV51727473; called by muse, mutect2, varscan2
- DNAH7 | c.4452G>T p.T1484= | Silent (SNP) | VAF 158/771 reads (20%) | catalogued as COSV100417806; called by muse, mutect2, varscan2
- DNAH9 | c.9162G>A p.L3054= | Silent (SNP) | VAF 54/375 reads (14%) | catalogued as rs752896577; called by muse, mutect2, varscan2
- FAT4 | c.12504T>C p.C4168= | Silent (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- FHL5 | c.201C>T p.F67= | Silent (SNP) | VAF 36/200 reads (18%) | called by muse, mutect2, varscan2
- FNIP1 | c.978G>A p.R326= | Silent (SNP) | VAF 32/304 reads (11%) | called by muse, mutect2, varscan2
- FOXG1 | c.822G>T p.R274= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV57399381; called by muse, mutect2, varscan2
- GALNT13 | c.1488C>T p.C496= | Silent (SNP) | VAF 32/183 reads (17%) | catalogued as COSV67224036; called by muse, mutect2, varscan2
- GPR137 | c.603G>A p.A201= | Silent (SNP) | VAF 47/390 reads (12%) | catalogued as rs752598687; called by muse, mutect2, varscan2
- GPR161 | c.534T>C p.C178= | Silent (SNP) | VAF 57/478 reads (12%) | called by muse, mutect2, varscan2
- GPR78 | c.906C>T p.R302= | Silent (SNP) | VAF 82/470 reads (17%) | catalogued as rs761866650; called by muse, mutect2, varscan2
- HSD17B3 | c.261C>T p.A87= | Silent (SNP) | VAF 124/450 reads (28%) | catalogued as rs1382522507; called by muse, mutect2, varscan2
- IGLV2-11 | c.303T>G p.A101= | Silent (SNP) | VAF 74/866 reads (9%) | called by muse, mutect2
- IQGAP2 | c.4581T>C p.G1527= | Silent (SNP) | VAF 65/240 reads (27%) | called by muse, mutect2, varscan2
- ITGA8 | c.1566A>G p.R522= | Silent (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- JUND | c.645C>T p.F215= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV53254914; called by mutect2, varscan2
- KCNT1 | c.2062C>A p.R688= (on ENST00000488444; = p.R707= on NM_020822.3) | Silent (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- KNDC1 | c.3675C>T p.P1225= | Silent (SNP) | VAF 83/537 reads (15%) | catalogued as rs1429256408; called by muse, mutect2, varscan2
- LGR4 | c.1008T>C p.N336= | Silent (SNP) | VAF 37/274 reads (14%) | called by muse, mutect2, varscan2
- LPO | c.2022C>A p.T674= | Silent (SNP) | VAF 44/550 reads (8%) | called by muse, mutect2
- LRRK2 | c.1074G>A p.T358= | Silent (SNP) | VAF 13/359 reads (4%) | catalogued as rs978206271, COSV54158811; called by muse, mutect2
- MAGEB18 | c.453A>G p.R151= | Silent (SNP) | VAF 53/199 reads (27%) | called by muse, mutect2, varscan2
- MC2R | c.670C>T p.L224= | Silent (SNP) | VAF 30/514 reads (6%) | catalogued as COSV59618357; called by muse, mutect2
- MLLT1 | c.1062G>T p.L354= | Silent (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- MUC6 | c.6273G>T p.S2091= | Silent (SNP) | VAF 92/769 reads (12%) | catalogued as rs377729497; called by muse, mutect2, varscan2
- MYH1 | c.1128T>G p.A376= | Silent (SNP) | VAF 57/483 reads (12%) | called by muse, mutect2, varscan2
- NEFM | c.111G>A p.S37= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs371903773; called by mutect2, varscan2
- NKX6-2 | c.540T>C p.R180= | Silent (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2, varscan2
- NTSR1 | c.525G>A p.K175= | Silent (SNP) | VAF 33/212 reads (16%) | catalogued as rs759768471; called by muse, mutect2, varscan2
- NUP153 | c.1167T>A p.P389= | Silent (SNP) | VAF 75/424 reads (18%) | called by muse, mutect2, varscan2
- OR11L1 | c.138C>T p.I46= | Silent (SNP) | VAF 46/622 reads (7%) | catalogued as COSV100869497; called by muse, mutect2
- OR52E6 | c.243C>T p.P81= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV61431947; called by muse, mutect2, varscan2
- OR7A10 | c.633C>T p.L211= | Silent (SNP) | VAF 35/353 reads (10%) | catalogued as COSV50166428; called by muse, mutect2, varscan2
- OTOP1 | c.258C>A p.G86= | Silent (SNP) | VAF 26/159 reads (16%) | called by muse, mutect2, varscan2
- PEAK1 | c.1050A>G p.E350= | Silent (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
- PHIP | c.2937G>C p.R979= | Silent (SNP) | VAF 52/259 reads (20%) | called by muse, mutect2, varscan2
- PNLIP | c.795A>T p.I265= | Silent (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- PRAMEF14 | c.1416T>A p.L472= | Silent (SNP) | VAF 29/238 reads (12%) | called by muse, mutect2, varscan2
- PSD4 | c.2800C>T p.L934= | Silent (SNP) | VAF 15/198 reads (8%) | catalogued as COSV99830726; called by muse, mutect2
- RBBP6 | c.2562A>T p.S854= | Silent (SNP) | VAF 64/246 reads (26%) | called by muse, mutect2, varscan2
- RFX7 | c.2937A>G p.S979= (on ENST00000559447 / NM_001368074.1; = p.S1076= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/459 reads (12%) | catalogued as COSV57964950; called by muse, mutect2, varscan2
- RNF144B | c.207T>C p.C69= | Silent (SNP) | VAF 45/426 reads (11%) | called by muse, mutect2, varscan2
- RPRD2 | c.2808A>T p.S936= | Silent (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- RTP5 | c.570C>T p.T190= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV58321883; called by muse, mutect2, varscan2
- SERPINB13 | c.672C>T p.F224= | Silent (SNP) | VAF 14/304 reads (5%) | catalogued as COSV54027826; called by muse, mutect2
- SERPINE2 | c.51C>A p.S17= | Silent (SNP) | VAF 48/240 reads (20%) | catalogued as COSV51457016; called by muse, mutect2, varscan2
- SLC10A4 | c.195C>A p.T65= | Silent (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- SMTNL1 | c.30G>A p.E10= | Silent (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- SOAT2 | c.1296G>A p.V432= | Silent (SNP) | VAF 47/267 reads (18%) | catalogued as rs1297560110; called by muse, mutect2, varscan2
- SORBS2 | c.48A>G p.P16= (on ENST00000284776 / NM_021069.5; = p.P62= on NM_003603.6) | Silent (SNP) | VAF 35/303 reads (12%) | called by muse, mutect2, varscan2
- SPG11 | c.2787T>G p.T929= | Silent (SNP) | VAF 58/506 reads (11%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2211T>C p.P737= | Silent (SNP) | VAF 73/533 reads (14%) | called by muse, mutect2, varscan2
- STPG1 | c.471C>T p.V157= (on ENST00000337248 / NM_001199013.2; = p.V110= on NM_178122.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- SUPT20HL2 | c.702G>A p.P234= | Silent (SNP) | VAF 118/258 reads (46%) | called by muse, mutect2, varscan2
- SYT9 | c.486C>G p.T162= | Silent (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2
- TEAD1 | c.837G>A p.K279= | Silent (SNP) | VAF 28/646 reads (4%) | catalogued as rs894159423; called by muse, mutect2
- THSD1 | c.400T>C p.L134= | Silent (SNP) | VAF 39/534 reads (7%) | called by muse, mutect2
- TRA2A | c.63A>T p.P21= | Silent (SNP) | VAF 30/523 reads (6%) | called by muse, mutect2
- TRIM38 | c.627G>A p.L209= | Silent (SNP) | VAF 69/768 reads (9%) | called by muse, mutect2
- TTN | c.31233C>A p.V10411= (on ENST00000591111; = p.V9484= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/313 reads (23%) | called by muse, mutect2, varscan2
- ZC3H12C | c.633G>C p.T211= | Silent (SNP) | VAF 32/343 reads (9%) | called by muse, mutect2
- ZFHX4 | c.6117A>T p.P2039= | Silent (SNP) | VAF 26/254 reads (10%) | called by mutect2, varscan2
- ZNF536 | c.3438C>A p.P1146= | Silent (SNP) | VAF 132/2788 reads (5%) | catalogued as COSV62832856; called by muse, mutect2
- ZP4 | c.918C>T p.P306= | Silent (SNP) | VAF 95/479 reads (20%) | called by muse, mutect2, varscan2
- AC002519.1 | chr16:31793858 G>A | 3'Flank (SNP) | VAF 28/125 reads (22%) | called by muse, mutect2, varscan2
- AC133561.1 | n.1512C>T | RNA (SNP) | VAF 19/190 reads (10%) | catalogued as rs62041118; called by muse, mutect2, varscan2
- AC243919.1 | n.423G>C | RNA (SNP) | VAF 43/383 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.2866-46G>A | Intron (SNP) | VAF 15/61 reads (25%) | catalogued as rs1555736725; called by muse, mutect2, varscan2
- AFAP1L2 | c.*25T>A | 3'UTR (SNP) | VAF 25/236 reads (11%) | called by muse, mutect2, varscan2
- AL353753.1 | n.345C>A | RNA (SNP) | VAF 39/197 reads (20%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.858+111C>A | Intron (SNP) | VAF 20/282 reads (7%) | catalogued as rs773878984, COSV56419900; called by muse, mutect2
- ASIC4 | chr2:219514472 ins GA | 5'Flank (INS) | VAF 37/255 reads (15%) | called by mutect2, pindel, varscan2
- ATP10B | c.-360G>C | 5'UTR (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- BOC | c.376+12C>G | Intron (SNP) | VAF 17/234 reads (7%) | called by muse, mutect2
- C8orf76 | c.-27C>A | 5'UTR (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- CD164 | c.*529T>A | 3'UTR (SNP) | VAF 31/149 reads (21%) | called by muse, mutect2, varscan2
- CELF2 | c.1075+64A>C | Intron (SNP) | VAF 68/819 reads (8%) | called by muse, mutect2
- CTSH | c.124-322T>C | Intron (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2
- DNM1P47 | n.2669G>T | RNA (SNP) | VAF 42/430 reads (10%) | catalogued as rs1435848150; called by muse, mutect2, varscan2
- DST | c.4297-4842G>T | Intron (SNP) | VAF 44/217 reads (20%) | called by muse, mutect2, varscan2
- FAM183BP | n.761G>T | RNA (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2
- FMN2 | c.-71G>C | 5'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- FOXP2 | c.*371A>C | 3'UTR (SNP) | VAF 95/399 reads (24%) | called by muse, mutect2, varscan2
- GAB1 | c.1586-1691A>T | Intron (SNP) | VAF 17/136 reads (13%) | called by muse, mutect2, varscan2
- GALNS | c.121-253C>T | Intron (SNP) | VAF 29/315 reads (9%) | catalogued as rs1279780931; called by muse, mutect2
- GUCY1B2 | n.1046G>A | RNA (SNP) | VAF 123/547 reads (22%) | called by muse, mutect2, varscan2
- HNRNPA3P1 | n.103A>C | RNA (SNP) | VAF 24/488 reads (5%) | called by muse, mutect2
- KCNU1 | c.2010-16922T>G | Intron (SNP) | VAF 33/233 reads (14%) | called by muse, mutect2, varscan2
- LAMA1 | c.8095-54C>T | Intron (SNP) | VAF 59/712 reads (8%) | called by muse, mutect2
- LARP6 | c.200+2162del | Intron (DEL) | VAF 26/188 reads (14%) | catalogued as COSV54583117; called by mutect2, pindel, varscan2
- LHX2 | c.-24C>G | 5'UTR (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2
- LINC00544 | n.775C>T | RNA (SNP) | VAF 37/456 reads (8%) | called by muse, mutect2
- LTO1 | c.50+258G>A | Intron (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- MAGI2 | c.2311+12T>A | Intron (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- MIR205 | n.102G>C | RNA (SNP) | VAF 209/792 reads (26%) | called by muse, mutect2, varscan2
- MLIP | c.613-11635T>C | Intron (SNP) | VAF 29/325 reads (9%) | called by muse, mutect2
- MMS22L | c.607-266G>T | Intron (SNP) | VAF 42/195 reads (22%) | called by muse, mutect2, varscan2
- NME3 | c.46+16C>A | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- OR2U1P | n.827T>G | RNA (SNP) | VAF 33/230 reads (14%) | called by muse, mutect2, varscan2
- OR56B3P | n.830G>C | RNA (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2
- PAX5 | c.*56A>G | 3'UTR (SNP) | VAF 70/347 reads (20%) | catalogued as rs113670785; called by muse, mutect2, varscan2
- PAX6 | c.1032+115A>T | Intron (SNP) | VAF 45/415 reads (11%) | called by muse, mutect2, varscan2
- PDE10A | c.-35T>G | 5'UTR (SNP) | VAF 43/225 reads (19%) | called by muse, mutect2, varscan2
- PIKFYVE | chr2:208360221 A>G | 3'Flank (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- PKD1L2 | n.3026T>G | RNA (SNP) | VAF 46/446 reads (10%) | called by muse, mutect2
- POLR1H | chr6:30057326 T>G | 5'Flank (SNP) | VAF 26/260 reads (10%) | called by muse, mutect2
- PRDM11 | chr11:45226411 G>A | 3'Flank (SNP) | VAF 12/238 reads (5%) | catalogued as COSV55438561; called by muse, mutect2
- RCBTB2 | chr13:48533082 C>G | 5'Flank (SNP) | VAF 16/85 reads (19%) | catalogued as rs759636619; called by muse, mutect2, varscan2
- RCOR3 | c.902-384C>T | Intron (SNP) | VAF 19/87 reads (22%) | catalogued as rs1460924915; called by muse, mutect2, varscan2
- RCOR3 | c.902-383G>T | Intron (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- RECK | c.-26C>A | 5'UTR (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- SHH | c.*2798C>T | 3'UTR (SNP) | VAF 24/743 reads (3%) | called by muse, mutect2
- SHISA9 | c.-22C>A | 5'UTR (SNP) | VAF 28/90 reads (31%) | called by muse, mutect2, varscan2
- ST3GAL5 | c.319-4993C>T | Intron (SNP) | VAF 35/246 reads (14%) | catalogued as rs763659230; called by muse, mutect2, varscan2
- STK24-AS1 | chr13:98576763 C>A | 5'Flank (SNP) | VAF 13/159 reads (8%) | called by muse, mutect2
- TMEM230 | c.-97A>T | 5'UTR (SNP) | VAF 62/175 reads (35%) | called by muse, mutect2, varscan2
- TSGA10 | c.*28A>T | 3'UTR (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2, varscan2
- TSPAN7 | c.82-43116A>C | Intron (SNP) | VAF 49/249 reads (20%) | called by muse, mutect2, varscan2
- UBR7 | c.*639A>G | 3'UTR (SNP) | VAF 80/1010 reads (8%) | called by muse, mutect2
- UGT3A1 | c.843+2518A>G | Intron (SNP) | VAF 34/680 reads (5%) | called by muse, mutect2
- VMP1 | c.*1389G>C | 3'UTR (SNP) | VAF 41/137 reads (30%) | called by muse, mutect2, varscan2
- VSTM5 | c.*12C>A | 3'UTR (SNP) | VAF 85/328 reads (26%) | called by muse, mutect2, varscan2
- ZNF777 | c.*304G>T | 3'UTR (SNP) | VAF 140/609 reads (23%) | catalogued as COSV56096718; called by muse, mutect2, varscan2
